Somatic mutation profile of tumor specimen C3L-01861-01 (aliquot CPT0092280009) from CPTAC case C3L-01861, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 57.4 years (20,974 days).
Specimen C3L-01861-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c664c07-04a5-4fdf-9304-825cbd078c55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01861-31 (Blood Derived Normal), aliquot CPT0093770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef7298a3-2d53-4471-8e20-0964672f13a0

The open-access MAF lists 65 somatic variants for this specimen: 47 protein-altering or splice-affecting, 8 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 8, Intron 7, Frame Shift Del 7, Frame Shift Ins 3, 3'UTR 2, Splice Region 2, In Frame Del 2, Splice Site 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.4240C>T p.Q1414* (on ENST00000372530 / NM_001198934.2; = p.Q1386* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/123 reads (19%) | catalogued as rs759919213; called by muse, mutect2, varscan2
- DNAAF4 | c.406-1G>T p.X136_splice | Splice Site (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100336543; called by muse, mutect2
- EFEMP1 | c.81G>A p.T27= | Splice Region (SNP) | VAF 16/478 reads (3%) | catalogued as COSV62615170; called by muse, mutect2
- FAM71B | c.52A>G p.M18V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs763029396, COSV100262263; called by muse, mutect2
- HDAC9 | c.2370-2A>G p.X790_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | catalogued as COSV67783797; called by muse, mutect2, varscan2
- ID2 | c.24G>C p.R8S | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV52170176; called by muse, varscan2
- MAP1B | c.6850G>C p.V2284L | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs1156555263; called by muse, mutect2, varscan2
- NLRC3 | c.977G>A p.C326Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs369331984; called by muse, mutect2, varscan2
- PCDHB11 | c.909A>T p.L303F | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV61313055; called by muse, mutect2
- SEMA3A | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1353490966; called by muse, mutect2, varscan2
- TXNDC11 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1252420989; called by muse, mutect2, varscan2
- USH2A | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as rs754523763, COSV56403480; called by muse, mutect2, varscan2
- ZNF229 | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs372929381; called by muse, mutect2, varscan2
- ZNF337 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53323393; called by muse, mutect2, varscan2
- AL035460.1 | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ASB4 | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CCDC168 | c.1718G>C p.G573A | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CEP78 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CHRNG | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRNKL1 | c.2259G>A p.M753I | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CWC25 | c.416dup p.F140Lfs*17 | Frame Shift Ins (INS) | VAF 14/93 reads (15%) | called by mutect2, pindel, varscan2
- DDX43 | c.1065_1066insT p.D356* | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- DMXL2 | c.3619A>G p.S1207G | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC8 | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FTH1 | c.115-6T>G | Splice Region (SNP) | VAF 81/425 reads (19%) | called by muse, mutect2, varscan2
- ID2 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, varscan2
- IRS2 | c.1760T>C p.V587A | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIRREL3 | c.1621del p.A541Pfs*2 | Frame Shift Del (DEL) | VAF 35/182 reads (19%) | called by mutect2, pindel, varscan2
- LARP1B | c.457dup p.R153Kfs*19 | Frame Shift Ins (INS) | VAF 36/260 reads (14%) | called by mutect2, pindel, varscan2
- LILRB1 | c.225del p.T76Pfs*6 (on ENST00000427581; = p.T40Pfs*6 on NM_006669.6) | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | called by mutect2, pindel, varscan2
- LRRC10 | c.294del p.K98Nfs*20 | Frame Shift Del (DEL) | VAF 32/230 reads (14%) | called by mutect2, pindel, varscan2
- MLC1 | c.443T>A p.L148Q | Missense Mutation (SNP) | VAF 73/495 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOB3A | c.287del p.K96Sfs*27 | Frame Shift Del (DEL) | VAF 40/249 reads (16%) | called by mutect2, pindel, varscan2
- PARP16 | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PBRM1 | c.2614_2625del p.F872_I875del | In Frame Del (DEL) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- PIEZO2 | c.2419T>C p.Y807H | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PKD2L2 | c.1679A>C p.Q560P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- POGLUT3 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- RECQL | c.1670A>C p.E557A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- RHBDL3 | c.1010_1016del p.H337Pfs*20 | Frame Shift Del (DEL) | VAF 52/299 reads (17%) | called by mutect2, pindel, varscan2
- ROCK2 | c.1704T>A p.N568K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2
- SHANK2 | c.5225G>A p.S1742N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- SUMO2 | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SUPT6H | c.1224C>G p.I408M | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- VHL | c.168del p.R58Gfs*9 | Frame Shift Del (DEL) | VAF 53/244 reads (22%) | called by mutect2, pindel, varscan2
- XKR6 | c.515_529del p.P172_V176del | In Frame Del (DEL) | VAF 49/318 reads (15%) | called by mutect2, varscan2
- ZNF462 | c.3711_3726del p.C1237* | Frame Shift Del (DEL) | VAF 27/158 reads (17%) | called by mutect2, pindel, varscan2
- F12 | c.495T>A p.G165= | Silent (SNP) | VAF 87/562 reads (15%) | called by muse, mutect2, varscan2
- LRP2 | c.6381T>A p.I2127= | Silent (SNP) | VAF 28/190 reads (15%) | called by muse, mutect2, varscan2
- LRP2 | c.6246T>C p.D2082= | Silent (SNP) | VAF 37/250 reads (15%) | called by muse, mutect2, varscan2
- MAP2K3 | c.720G>A p.L240= (on ENST00000342679 / NM_145109.3; = p.L211= on NM_002756.4) | Silent (SNP) | VAF 41/487 reads (8%) | catalogued as COSV57567395; called by muse, mutect2
- SNX5 | c.654C>T p.N218= | Silent (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- TEDDM1 | c.798C>G p.L266= | Silent (SNP) | VAF 35/135 reads (26%) | called by muse, varscan2
- TRIM6 | c.945C>A p.V315= | Silent (SNP) | VAF 28/134 reads (21%) | called by muse, mutect2
- YOD1 | c.102G>A p.A34= | Silent (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- CABIN1 | c.4117+31C>T | Intron (SNP) | VAF 49/293 reads (17%) | catalogued as rs754732045; called by muse, mutect2, varscan2
- CACNB2 | c.214-60953T>A | Intron (SNP) | VAF 16/369 reads (4%) | called by muse, mutect2
- CHD3 | c.5591-54T>G | Intron (SNP) | VAF 42/180 reads (23%) | called by muse, mutect2
- LMOD1 | c.*19C>G | 3'UTR (SNP) | VAF 39/243 reads (16%) | called by muse, mutect2, varscan2
- LMOD1 | c.*18C>T | 3'UTR (SNP) | VAF 39/244 reads (16%) | catalogued as rs766264807; called by muse, mutect2, varscan2
- MTMR14 | c.-6T>C | 5'UTR (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2
- MTMR14 | c.1770-30T>G | Intron (SNP) | VAF 69/277 reads (25%) | called by muse, mutect2, varscan2
- NAP1L1 | c.1089+234T>A | Intron (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- SEC14L2 | c.55-902C>A | Intron (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+2771A>T | Intron (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
